Somatic mutation profile of tumor specimen TCGA-W2-A7HB-01A (aliquot TCGA-W2-A7HB-01A-11D-A35I-08) from TCGA case TCGA-W2-A7HB, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 24.6 years (8,979 days).
Specimen TCGA-W2-A7HB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91eb8284-9f1d-46fd-b25b-14d7e5a5fb21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W2-A7HB-10A (Blood Derived Normal), aliquot TCGA-W2-A7HB-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99906384-7919-4842-a48a-80dd0b2a4675

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H2BC4 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV58414879, COSV58417027; called by muse, mutect2, varscan2
- AFF4 | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ATP1B4 | c.517G>C p.D173H (on ENST00000218008 / NM_001142447.3; = p.D169H on NM_012069.5) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HTT | c.8642G>T p.G2881V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAPK6 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- BARHL1 | c.48C>T p.R16= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs757098264, COSV55036748, COSV55037086; called by muse, mutect2, varscan2
- SPTB | c.5751C>T p.S1917= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
